Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UC-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1-"Biopsy of cervical tumor":

Invasive squamous cell carcinoma.

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C539
JAD 3/7/14

Source: NCI Genomic Data Commons file 62cba3c5-ccbd-4fb8-bbb0-2121b2c5e42d (TCGA-VS-A9UC.F7CE1EAA-6332-4A64-88C8-3BB5905380AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).